Gene-level copy-number profile of tumor specimen TCGA-21-5786-01A from TCGA case TCGA-21-5786, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.7 years (23,649 days).
Specimen TCGA-21-5786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a498ecc5-b02a-4d03-8635-733d5f22fcca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-5786-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1cecf25b-bc42-4ec9-a45c-04746d067aa1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16; copy number 2: 28,367; copy number 3: 15,788; copy number 4: 10,213; copy number 5: 965; copy number 6: 2,200; copy number 7: 127; copy number 8: 617; copy number 9: 1,014; copy number 10: 9; copy number 11: 243; copy number 12: 87; copy number 13: 129; copy number 16: 7; copy number 17: 19; copy number 19: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-5786-01A-01D-1631-01): tumor purity 0.58, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,433 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–34,738,231, 583 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:43,831,942–44,772,592, 14 genes, copy number 13 (within-gene range 4–13): ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT.
- chr2:45,164,816–86,142,157, 699 genes, copy number 6–16 (broad region; genes not listed).
- chr2:96,248,514–99,401,326, 87 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr2:99,405,218–99,405,843, 1 gene, copy number 8: AC018690.1.
- chr2:105,600,703–115,940,291, 231 genes, copy number 6–19 (within-gene range 2–19) (broad region; genes not listed).
- chr2:117,915,478–121,728,563, 58 genes, copy number 8–17 (within-gene range 2–17): CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2.
- chr2:145,294,277–146,145,217, 9 genes, copy number 8: AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1, AC079248.1, AC079248.2, RNU7-2P.
- chr5:58,198–40,312,905, 621 genes, copy number 6 (broad region; genes not listed).
- chr6:60,719,222–60,942,327, 5 genes, copy number 16: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr6:89,886,156–94,447,179, 40 genes, copy number 6–7: AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr7:83,955,777–108,952,666, 502 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:98,904,603–145,066,685, 733 genes, copy number 5 (broad region; genes not listed).
- chr11:44,047,981–47,715,389, 108 genes, copy number 5–6 (broad region; genes not listed).
- chr11:68,683,779–71,252,577, 64 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).
- chr12:65,169,583–71,441,898, 123 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:73,648,666–73,846,188, 4 genes, copy number 5: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–73,919,337, 1 gene, copy number 5: AC136188.1.
- chr14:25,647,304–26,143,305, 4 genes, copy number 5 (within-gene range 2–5): LINC02306, AL359396.1, AL359396.2, AL132633.1.
- chr17:20,771,058–21,641,536, 40 genes, copy number 13: HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1.
- chr20:87,250–33,243,311, 656 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
